TCGA case TCGA-DX-AB2X — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9dcdbd1b-2e03-4314-aef2-1f6b6fe18523

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Dead; Days to death: 404 days (1.1 years).

Diagnoses (4)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 73.2 years (26,736 days); Year of diagnosis: 2010; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 8; Tumor width measurement: 6.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 20; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Upper limb, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 62.3 years (22,767 days); Days to diagnosis: -3,969 days (-10.9 years).
3. Recurrence of diagnosis 1 (Undifferentiated sarcoma). Age at diagnosis: 73.5 years (26,847 days); Days to diagnosis: 111 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 1.2; Tumor length measurement: 3; Tumor width measurement: 2.2.
4. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lung, NOS. Age at diagnosis: 73.8 years (26,954 days); Days to diagnosis: 218 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 111 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 111 days.
- Day 218 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 218 days.
- Days to follow up: 404 days (1.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-AB2X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 750 mg.
  Slide TCGA-DX-AB2X-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-AB2X-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-AB2X-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 8; Lesion pathologic width: 6; Lesion pathologic depth: 3.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Forearm; Other malignancy histological type: Melanoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Excision; Days from index date to other malignancy surgery: -3963.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 404 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 404 days; disease-free interval: event (new tumor event after initially disease-free), 111 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 111 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-AB2X-01A-11D-A386-01): tumor purity 0.8, ploidy 2.69, whole-genome doublings 1.
